Gene-level copy-number profile of tumor specimen ALCH-ABOQ-TTP1-A from ALCHEMIST case ALCH-ABOQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.1 years (21,569 days).
Specimen ALCH-ABOQ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 921828b1-4597-46be-a7e5-e84669cc9645.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABOQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/cf3c0cdb-338a-44b2-a2a6-18d79f9d3a38

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,049; copy number 2: 50,736; copy number 3: 3,946; copy number 4: 135; copy number 5: 10; copy number 6: 2; copy number 10: 2; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes, copy number 5: AC239859.5, RNA5SP533, AC239859.3.
- chr7:74,606,913–74,633,884, 2 genes, copy number 5: AC211433.2, AC211433.3.
- chr8:6,977,649–6,989,721, 2 genes, copy number 6: DEFA1, DEFT1P.
- chr14:18,977,180–18,980,742, 2 genes, copy number 10 (within-gene range 3–10): AL929601.3, RNU6-1239P.
- chr16:28,700,294–28,701,540, 1 gene, copy number 11 (within-gene range 9–11): CDC37P1.
- chr22:18,605,355–18,611,919, 3 genes, copy number 5: AC023490.1, RN7SKP131, RIMBP3.
- chr22:18,623,339–18,638,405, 2 genes, copy number 5: SUSD2P2, CA15P2.

Autosomal genes at a single copy (total copy number 1): 1,318. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
